Somatic mutation profile of tumor specimen MP2PRT-PASLVA-TMP1-A (aliquot MP2PRT-PASLVA-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASLVA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (749 days).
Specimen MP2PRT-PASLVA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ada3ad14-83e3-4f41-8440-70dcb0d2664a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLVA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLVA-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a51fed78-2028-4a13-8555-a990e3ad3fde

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 18/129 reads (14%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/168 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4463C>T p.P1488L | Missense Mutation (SNP) | VAF 118/255 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52116625, COSV52132987, COSV52135343; called by muse, mutect2, varscan2
- HYDIN | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372720976, COSV55481350; called by muse, mutect2, varscan2
- IKZF1 | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58784013, COSV58793145; called by muse, mutect2, varscan2
- KCNS2 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1380809648; called by muse, mutect2, varscan2
- SERTAD4 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150924683; called by muse, mutect2, varscan2
- TMEM198 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 167/363 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs369931895, COSV99525431; called by muse, varscan2
- POLE | c.2521_2522insCCGGG p.N841Tfs*11 | Frame Shift Ins (INS) | VAF 23/299 reads (8%) | called by mutect2, pindel*
- ANK3 | c.5982G>A p.S1994= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as rs148277967; called by muse, mutect2, varscan2
